Somatic mutation profile of tumor specimen MP2PRT-PARWLG-TMP1-A (aliquot MP2PRT-PARWLG-TMP1-A-1-0-D-A82L-36) from MP2PRT case MP2PRT-PARWLG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.6 years (946 days).
Specimen MP2PRT-PARWLG-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d68fed22-37c0-4feb-86ab-14a2309b7dd6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARWLG-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARWLG-NM1-A-1-0-D-A82L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/060fc8ad-af11-436b-a103-64e87836ffcb

The open-access MAF lists 21 somatic variants for this specimen: 19 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 17, Silent 2, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.387C>A p.Y129* | Nonsense Mutation (SNP) | VAF 568/1067 reads (53%) | hotspot (GDC flag); catalogued as COSV58684005, COSV58689871; called by muse, mutect2, varscan2
- ATAD5 | c.688A>T p.K230* | Nonsense Mutation (SNP) | VAF 85/266 reads (32%) | catalogued as COSV58972719; called by muse, mutect2, varscan2
- DDX53 | c.1870C>A p.R624S | Missense Mutation (SNP) | VAF 94/344 reads (27%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as COSV60070412; called by muse, mutect2, varscan2
- H3C8 | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 19/511 reads (4%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.049); catalogued as rs1436484851, COSV100010015; called by muse, mutect2
- IGBP1P2 | c.869C>A p.A290E | Missense Mutation (SNP) | VAF 128/436 reads (29%) | SIFT tolerated (0.82); PolyPhen benign (0.005); catalogued as rs376798465; called by muse, mutect2, varscan2
- KRTAP26-1 | c.59G>A p.R20H | Missense Mutation (SNP) | VAF 36/483 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs763814850, COSV62128517; called by muse, mutect2
- MARCHF10 | c.815G>A p.R272Q | Missense Mutation (SNP) | VAF 19/425 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.668); catalogued as rs748506169, COSV60886589; called by muse, mutect2
- NLRP4 | c.1715T>A p.L572H | Missense Mutation (SNP) | VAF 148/456 reads (32%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.789); catalogued as rs772397628; called by muse, mutect2, varscan2
- OR5K3 | c.580A>T p.I194F | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as COSV67349914; called by muse, mutect2, varscan2
- PAX5 | c.91C>T p.R31W | Missense Mutation (SNP) | VAF 195/390 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63905553; called by muse, mutect2, varscan2
- PCDHGA8 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 30/401 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.934); catalogued as COSV53986400; called by muse, mutect2
- PLPPR2 | c.481G>A p.V161M | Missense Mutation (SNP) | VAF 254/851 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1294640274; called by muse, mutect2, varscan2
- STK36 | c.1144C>T p.R382W | Missense Mutation (SNP) | VAF 78/296 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs199949532, COSV55332271; called by muse, mutect2
- TRUB2 | c.769C>T p.R257C | Missense Mutation (SNP) | VAF 216/596 reads (36%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as rs755835163; called by muse, mutect2, varscan2
- DNAH9 | c.7024C>A p.Q2342K | Missense Mutation (SNP) | VAF 25/485 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.09); called by muse, mutect2
- IGKV1D-8 | c.262_266delinsCCGGG p.G88_S89delinsPG | Missense Mutation (ONP) | VAF 67/214 reads (31%) | called by mutect2*, pindel, varscan2*
- IGKV2D-30 | chr2:89937676 GCCTCCCACAGTG>CCCA | Missense Mutation (DEL) | VAF 8/87 reads (9%) | called by pindel, varscan2*
- IQSEC3 | c.3184G>T p.V1062L | Missense Mutation (SNP) | VAF 238/826 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PAX5 | c.244_250delinsAGCCCCC p.V82_G84delinsSPR | Missense Mutation (ONP) | VAF 139/323 reads (43%) | called by pindel, varscan2*
- CPA4 | c.723G>A p.T241= | Silent (SNP) | VAF 99/334 reads (30%) | catalogued as rs1314117954, COSV55983571; called by muse, mutect2, varscan2
- TNFRSF11B | c.315C>T p.C105= | Silent (SNP) | VAF 111/441 reads (25%) | catalogued as rs751552719, COSV99816473; ClinVar: uncertain significance; called by muse, mutect2, varscan2
